Somatic mutation profile of tumor specimen TCGA-UB-AA0V-01A (aliquot TCGA-UB-AA0V-01A-11D-A382-10) from TCGA case TCGA-UB-AA0V, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 69.4 years (25,340 days).
Specimen TCGA-UB-AA0V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cbaa84f-2a8c-420f-aeea-c24ac15bf5a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-AA0V-10A (Blood Derived Normal), aliquot TCGA-UB-AA0V-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dfcef15-686e-49a9-9616-0fe2aa2b2105

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Nonsense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSPRY | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773758644, COSV100949509; called by muse, mutect2, varscan2
- CACNA1D | c.5399G>T p.S1800I (on ENST00000350061 / NM_001128840.3; = p.S1820I on NM_000720.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV55439346, COSV99857610; called by muse, mutect2, varscan2
- CTNNA3 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as COSV100373499; called by muse, mutect2, varscan2
- DRP2 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100871870, COSV65811879; called by muse, mutect2, varscan2
- DTX2 | c.1429G>T p.G477* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | catalogued as COSV100184535; called by muse, mutect2
- EDA2R | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99490617; called by muse, mutect2, varscan2
- EPB42 | c.287A>T p.E96V (on ENST00000441366 / NM_001114134.2; = p.E126V on NM_000119.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV100281912; called by muse, mutect2
- ERCC4 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100318806; called by muse, mutect2, varscan2
- FATE1 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 35/211 reads (17%) | catalogued as COSV100948136; called by muse, mutect2, varscan2
- GNMT | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99769703; called by muse, mutect2, varscan2
- HECTD2 | c.1815A>T p.K605N | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as COSV53220004, COSV99978431; called by muse, mutect2
- KAT2A | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1203283266, COSV99288176; called by muse, mutect2
- KDM4B | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99346205; called by muse, mutect2
- LUM | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); catalogued as COSV99898955; called by muse, mutect2
- MYO10 | c.452A>G p.Q151R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101549854; called by muse, mutect2, varscan2
- PHYKPL | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.812); catalogued as rs780234084, COSV100069511; called by muse, mutect2, varscan2
- PRKD2 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV99354228; called by muse, mutect2
- PSME4 | c.2747A>C p.K916T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101122442, COSV101122538; called by muse, mutect2, varscan2
- RXFP1 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313693; called by muse, mutect2, varscan2
- SYN3 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs865899525, COSV60508627; called by muse, mutect2, varscan2
- TATDN3 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV100875210; called by muse, mutect2, varscan2
- TFB1M | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100905183; called by muse, mutect2, varscan2
- TRIM26 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs371459188; called by muse, mutect2, varscan2
- UPF1 | c.1280A>G p.K427R (on ENST00000599848 / NM_001297549.2; = p.K416R on NM_002911.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV99439355; called by muse, mutect2
- ZNF611 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60539558; called by muse, mutect2, varscan2
- MRC1 | c.3020C>A p.A1007D | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); called by muse, mutect2
- MUC2 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.36); called by muse, mutect2, varscan2
- PIP4K2B | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPATA31D1 | c.2209G>T p.V737F | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.02); called by muse, mutect2
- TNC | c.3260G>A p.W1087* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- CDC42BPB | c.4425C>T p.H1475= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs778075502, COSV100775369; called by muse, mutect2, varscan2
- CDKL5 | c.2103A>G p.R701= | Silent (SNP) | VAF 9/179 reads (5%) | catalogued as rs1470120191, COSV101184262; called by muse, mutect2
- EIF4A1 | c.39C>G p.G13= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99548875; called by muse, mutect2, varscan2
- GABRG2 | c.1458G>T p.R486= (on ENST00000361925 / NM_001375343.1; = p.R446= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as COSV100729593, COSV100729651; called by muse, mutect2
- GABRQ | c.561G>A p.L187= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV100941203, COSV64784308; called by muse, mutect2, varscan2
- GFOD2 | c.597G>C p.G199= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV99263505; called by muse, mutect2
- ICA1L | c.60A>G p.Q20= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100841737; called by muse, mutect2
- KLHL31 | c.1236C>T p.F412= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100911763; called by muse, mutect2, varscan2
- LONP1 | c.321G>A p.P107= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs760045514, COSV100638586; called by muse, mutect2, varscan2
- NPAP1 | c.2703T>C p.L901= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100275179; called by muse, mutect2, varscan2
- PEX7 | c.654G>T p.A218= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1414537422, COSV100576492, COSV59247897; called by muse, mutect2, varscan2
- SCRG1 | c.39T>A p.T13= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99633433; called by muse, mutect2
- SYPL2 | c.633G>T p.L211= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100881541; called by mutect2, varscan2
- TRAF7 | c.375C>G p.P125= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100399397; called by muse, varscan2
- CEP78 | c.1797+332A>G | Intron (SNP) | VAF 34/219 reads (16%) | catalogued as COSV99450258; called by muse, mutect2, varscan2
- POLA1 | c.2947-21211G>T | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
